Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MT, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MT-01A (Primary Tumor).

[page 1 of 2]
Specimen:
Procedure:
Accessioned:
Reported:
Submitting Phys:

Patient
Medical Record #:
DOB/Age/Sex:
Location/Client:

Account #:
F

Surgical Pathology Report

Final Diagnosis

LEFT, ADRENAL GLAND, ADRENALECTOMY:
- PHEOCHROMOCYTOMA.

SIZE OF TUMOR: 2.2 x 2 x 2 CM.

WEIGHT OF TUMOR: 41 GRAMS.

EXTENT OF TUMOR: TUMOR IS CONFINED TO THE ADRENAL GLAND.

MARGINS OF RESECTION: MARGINS ARE FREE OF TUMOR.

LYMPH NODES: NO LYMPH NODES RECEIVED WITH THE SPECIMEN.

ADDITIONAL TUMOR FEATURES:

- BLOOD VESSEL INVASION: NOT IDENTIFIED.
- LYMPH VESSEL INVASION: NOT IDENTIFIED.
- MITOTIC ACTIVITY: < 5/50 HIGH POWER FIELD.
- NUCLEAR ATYPIA: MILD.
- NECROSIS: ABSENT.
- IMMUNOSTAIN FOR MIB-1 SHOWS A LOW (<5%) NUCLEAR POSITIVITY.

PTN STAGE:

- PRIMARY STAGE: pT1
- REGIONAL LYMPH NODES: pNX
- DISTANT METASTASIS: pMX.

***Report Electronically Signed By

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Intra-Operative Consultation with Frozen Section

FROZEN SECTION DIAGNOSIS: LEFT ADRENAL WITH TUMOR:
- PHEOCHROMOCYTOMA.

Clinical History

rear old female with pheochromocytoma

Pre-Operative Diagnosis

(Not Provided)

[page 2 of 2]
Post-Operative Diagnosis
(Not Provided)

Gross Description

A. LEFT ADRENAL WITH TUMOR (FRESH): The specimen, labeled with the patient's name and accession number, consists of an adrenal gland which is enlarged and weighs 41 gm. It measures 7 x 2.5 x 2 cm. Fat is seen around the adrenal gland. On sectioning there is a large well encapsulated mass measuring 2.2 x 2 x 2 cm. It is gray brown homogeneous and fleshy. The capsule is intact. The rest of the adrenal gland is bright yellow and shows cortical hypertrophy. Very little of the medullar is identified. Part of the tumor is taken for frozen section and part of the tumor is given to Dr. The specimen is serially sectioned and submitted for permanent sections as follows: The tumor is submitted in toto.

SECTION CODES

A1: FROZEN SECTION.
A2-5: THE REST OF THE TUMOR.
A8-10: CORTEX WITHOUT THE TUMOR.

Department of Pathology
- End of Report -

Page 2 of 2
Printed:

Source: NCI Genomic Data Commons file 00c13a16-f072-4272-9559-564f86fcab7f (TCGA-SR-A6MT.0382E5E5-DF1A-4E99-B772-CEB0367D7136.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).